ALCHEMIST case ALCH-ADTR — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/e856cd85-529f-425e-9588-3b475ffc72f4

Demographics
Sex at birth: male.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: Age at diagnosis: 72.0 years (26,307 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-ADTR-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-ADTR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-ADTR-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 31; Percent tumor nuclei: 68; Percent normal cells: 45; Percent necrosis: 5; Percent stromal cells: 19; Percent lymphocyte infiltration: 17; Percent monocyte infiltration: 4; Percent neutrophil infiltration: 0.
